Somatic mutation profile of tumor specimen TCGA-CV-6950-01A (aliquot TCGA-CV-6950-01A-11D-1912-08) from TCGA case TCGA-CV-6950, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Base of tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 64.5 years (23,549 days).
Specimen TCGA-CV-6950-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 486ee8fb-a038-4c91-a1b9-6a56267088b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-6950-10A (Blood Derived Normal), aliquot TCGA-CV-6950-10A-01D-1912-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/429ca143-b732-4c21-b0fa-5ddd63e9fbd1

The open-access MAF lists 58 somatic variants for this specimen: 46 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 11, Nonsense Mutation 5, Frame Shift Del 2, In Frame Ins 1, In Frame Del 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTC1 | c.1015T>C p.Y339H | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.207); catalogued as COSV99291884, COSV99292219; called by muse, mutect2, varscan2
- ADH1C | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 72/282 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.634); catalogued as COSV101565211; called by muse, mutect2, varscan2
- AJUBA | c.1057C>T p.Q353* | Nonsense Mutation (SNP) | VAF 137/192 reads (71%) | catalogued as COSV52986672; called by muse, mutect2, varscan2
- AKAP9 | c.4207G>T p.G1403* | Nonsense Mutation (SNP) | VAF 54/109 reads (50%) | catalogued as COSV100663335; called by muse, mutect2, varscan2
- ANKH | c.340A>T p.I114F | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99416097; called by muse, mutect2, varscan2
- ARHGAP4 | c.349A>T p.S117C | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100604314; called by muse, mutect2, varscan2
- ASPM | c.3478G>T p.A1160S | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV54125156, COSV99661312; called by muse, mutect2, varscan2
- ATM | c.8247A>C p.K2749N | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.12); catalogued as COSV99592441; called by muse, mutect2, varscan2
- ATP11C | c.2788G>T p.E930* | Nonsense Mutation (SNP) | VAF 5/68 reads (7%) | catalogued as COSV100558836; called by muse, mutect2
- BSPRY | c.721C>T p.P241S | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99445260; called by muse, mutect2, varscan2
- CABIN1 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.193); catalogued as COSV99574222; called by muse, mutect2, varscan2
- COL5A1 | c.2529A>C p.E843D | Missense Mutation (SNP) | VAF 46/80 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100880701; called by muse, mutect2, varscan2
- CUX2 | c.2334G>T p.E778D | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99921022; called by muse, mutect2, varscan2
- DNAJC13 | c.4516C>T p.R1506W | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs370216085; called by muse, mutect2, varscan2
- FOXS1 | c.241C>A p.R81S | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54068006, COSV99640365; called by muse, mutect2, varscan2
- FRS3 | c.1432G>T p.G478C | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99443241; called by muse, varscan2
- GTF3A | c.437A>T p.H146L | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV100820216; called by muse, mutect2, varscan2
- IRGQ | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.977); catalogued as rs1436490844, COSV100338277; called by muse, mutect2, varscan2
- KLC1 | c.1717C>T p.R573C | Missense Mutation (SNP) | VAF 12/88 reads (14%) | PolyPhen benign (0); catalogued as rs766317490, COSV100572769, COSV57980149; called by muse, mutect2, varscan2
- MED12L | c.5689C>T p.Q1897* | Nonsense Mutation (SNP) | VAF 17/127 reads (13%) | catalogued as COSV99855121; called by muse, mutect2, varscan2
- MTSS1 | c.401G>T p.R134L | Missense Mutation (SNP) | VAF 53/182 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.147); catalogued as COSV100275828, COSV61500070; called by muse, mutect2, varscan2
- MYCBP2 | c.10589C>T p.A3530V (on ENST00000357337; = p.A3568V on NM_015057.5) | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100632368; called by muse, mutect2, varscan2
- PCDHGA3 | c.1093G>C p.E365Q | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.425); catalogued as COSV53983304, COSV99549007; called by muse, mutect2, varscan2
- PGBD2 | c.1273G>T p.A425S | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100252292; called by muse, mutect2, varscan2
- PKD1 | c.4918G>C p.G1640R | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV51917444, COSV99239279; called by muse, mutect2, varscan2
- PSME3 | c.94A>G p.N32D | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV53200302; called by muse, mutect2, varscan2
- PXDNL | c.3410C>T p.S1137L | Missense Mutation (SNP) | VAF 13/162 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62484880; called by muse, mutect2
- RFX3 | c.1489C>T p.R497* | Nonsense Mutation (SNP) | VAF 25/125 reads (20%) | catalogued as COSV100174997; called by muse, mutect2, varscan2
- RTTN | c.2886-1G>A p.X962_splice | Splice Site (SNP) | VAF 4/37 reads (11%) | catalogued as rs764126513, COSV99734077; called by mutect2, varscan2
- S1PR5 | c.779T>A p.F260Y | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100330826; called by muse, mutect2, varscan2
- SAFB2 | c.1321A>G p.N441D | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV99386154; called by muse, mutect2, varscan2
- SEC16A | c.5054G>A p.R1685Q | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775500259, COSV99260474; called by muse, varscan2
- SF3B1 | c.302A>G p.Y101C | Missense Mutation (SNP) | VAF 39/63 reads (62%) | SIFT tolerated (0.17); PolyPhen benign (0.428); catalogued as rs1234164862, COSV100136080; called by muse, mutect2, varscan2
- SLC28A3 | c.589G>T p.G197C | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100883371, COSV66153213; called by muse, mutect2, varscan2
- SOS2 | c.3100A>G p.K1034E | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV99366933; called by muse, mutect2
- SYNPO2 | c.2060C>A p.A687D | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100206556; called by muse, mutect2, varscan2
- TBC1D9B | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs755094235, COSV100783479; called by muse, mutect2, varscan2
- TBX20 | c.400C>G p.R134G | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101282441; called by muse, mutect2
- TEX47 | c.722T>C p.L241P | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV99787418; called by muse, mutect2, varscan2
- TP53 | c.608del p.V203Gfs*44 | Frame Shift Del (DEL) | VAF 29/56 reads (52%) | catalogued as COSV52661085, COSV52838983; called by mutect2, pindel, varscan2
- VIRMA | c.2327G>A p.S776N | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV99889737; called by muse, mutect2, varscan2
- KMT2D | c.3095_3102del p.L1032Pfs*33 | Frame Shift Del (DEL) | VAF 9/50 reads (18%) | called by mutect2, pindel, varscan2
- PRAMEF20 | c.770C>T p.T257I | Missense Mutation (SNP) | VAF 96/588 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- PRELP | c.122_123insTCCCAG p.P40_R41insSP | In Frame Ins (INS) | VAF 19/55 reads (35%) | called by mutect2, pindel, varscan2
- TRAV12-1 | c.275T>A p.I92N | Missense Mutation (SNP) | VAF 193/267 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- TRIM51 | c.1195_1197del p.V399del | In Frame Del (DEL) | VAF 20/94 reads (21%) | called by pindel, varscan2
- C3AR1 | c.75C>T p.L25= | Silent (SNP) | VAF 29/98 reads (30%) | catalogued as COSV99369105; called by muse, mutect2, varscan2
- CWH43 | c.1296C>A p.I432= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV99894302; called by muse, mutect2, varscan2
- DGKG | c.1482G>A p.G494= | Silent (SNP) | VAF 49/119 reads (41%) | catalogued as COSV99404635; called by muse, mutect2, varscan2
- GSS | c.1071C>T p.A357= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV99404662; called by muse, mutect2, varscan2
- GUCY2F | c.232T>C p.L78= | Silent (SNP) | VAF 39/58 reads (67%) | catalogued as COSV99485853; called by muse, mutect2, varscan2
- MXRA5 | c.1782G>A p.S594= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs756203907, COSV54224498; called by muse, mutect2, varscan2
- PARP15 | c.1875C>T p.F625= (on ENST00000464300 / NM_001113523.3; = p.F391= on NM_152615.2) | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV59972792; called by muse, mutect2, varscan2
- PKHD1 | c.10458G>A p.L3486= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV100945510; called by muse, mutect2, varscan2
- PXDNL | c.1671C>T p.F557= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV62480087, COSV62480761; called by muse, mutect2, varscan2
- UBR5 | c.6597A>T p.V2199= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV99642674; called by muse, mutect2, varscan2
- ZNF574 | c.1941C>T p.S647= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as rs373559000, COSV99726606; called by muse, mutect2, varscan2
- SLITRK2 | c.*2G>T | 3'UTR (SNP) | VAF 17/35 reads (49%) | catalogued as COSV100157345, COSV100158319; called by muse, mutect2, varscan2
